Gene-level copy-number profile of tumor specimen ALCH-ADUI-TTP1-A from ALCHEMIST case ALCH-ADUI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 58.3 years (21,299 days).
Specimen ALCH-ADUI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7853333e-db39-4e8f-92b3-fe17d9964f29.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADUI-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/08d6e279-7bad-47ce-b987-e5855465fe9f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 5,951; copy number 2: 49,711; copy number 3: 2,372; copy number 4: 483; copy number 5: 118; copy number 6: 171; copy number 7: 30; copy number 8: 22; copy number 10: 2; copy number 16: 25.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:6,424,776–6,466,175, 4 genes (within-gene range 0–2): ESPN, MIR4252, AL031848.1, TNFRSF25.
- chr1:15,720,312–15,749,896, 4 genes (within-gene range 0–2): AL450998.2, SLC25A34, SLC25A34-AS1, TMEM82.
- chr9:127,794,597–127,814,327, 1 gene: FPGS.
- chr12:131,828,393–131,851,783, 1 gene: MMP17.
- chr16:89,159,146–89,169,147, 2 genes: LINC00304, LINC02138.
- chr19:55,158,661–55,177,540, 3 genes (within-gene range 0–2): DNAAF3, AC010327.4, AC010327.1.
- chr20:62,332,487–62,332,557, 1 gene (within-gene range 0–2): MIR4758.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 368 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:1,507,322–2,917,733, 22 genes, copy number 5–8: RN7SL352P, AL512329.1, AL512329.2, FOXCUT, FOXC1, GMDS, AL035693.1, GMDS-DT, HMGN2P28, AL031768.2, AL031768.1, AL359852.1, LINC02521, LINC01600, MYLK4, WRNIP1, SERPINB1, SERPINB9P1, MIR4645, SERPINB9, AL133351.2, AL133351.1.
- chr11:68,612,899–70,436,584, 54 genes, copy number 7–16 (within-gene range 2–16): AP003096.1, GAL, TESMIN, CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr22:19,121,529–21,644,299, 143 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr22:21,697,536–23,164,350, 149 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,113. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
